Somatic mutation profile of tumor specimen TCGA-DH-5144-01A (aliquot TCGA-DH-5144-01A-01D-1468-08) from TCGA case TCGA-DH-5144, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 56.3 years (20,558 days).
Specimen TCGA-DH-5144-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4395f425-8730-46a6-af0d-72ae3bec29e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-5144-10A (Blood Derived Normal), aliquot TCGA-DH-5144-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5acbe113-8ecf-48d1-a95f-7037bf0d9361

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Splice Site 2, Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 52/66 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50560816, COSV50584645; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 76/165 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 55/126 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- ADAM20 | c.1880G>A p.S627N | Missense Mutation (SNP) | VAF 280/700 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV56454777; called by muse, mutect2, varscan2
- AMMECR1 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 153/330 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs1162756289, COSV53317379; called by muse, mutect2, varscan2
- ARNTL2 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53825158, COSV53828394; called by muse, mutect2, varscan2
- ATRX | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64869530; called by muse, mutect2, varscan2
- AZU1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs201462708; called by muse, mutect2, varscan2
- CFL1 | c.312-1G>A p.X104_splice | Splice Site (SNP) | VAF 6/99 reads (6%) | catalogued as COSV57379474; called by muse, mutect2
- CLEC4M | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs370560578, COSV50217617; called by muse, mutect2, varscan2
- COL4A5 | c.4486A>G p.K1496E | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV60360215; called by muse, mutect2
- CTSG | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs771506740, COSV53535252, COSV53536465; called by muse, mutect2, varscan2
- EXOC5 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); catalogued as rs1478032231, COSV61770612; called by muse, mutect2, varscan2
- FUBP1 | c.941-1G>A p.X314_splice | Splice Site (SNP) | VAF 139/159 reads (87%) | catalogued as COSV53929677; called by muse, mutect2, varscan2
- GDI1 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 319/856 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs782575041, COSV50131011, COSV50132161; called by muse, mutect2, varscan2
- GPR50 | c.1155C>A p.H385Q | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54438583; called by muse, mutect2, varscan2
- KIF16B | c.2032A>G p.K678E | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV61705160; called by muse, mutect2, varscan2
- KRT86 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 203/451 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs199678774; called by muse, mutect2, varscan2
- LRRC4C | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 200/381 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV53423455; called by muse, mutect2, varscan2
- MKRN2 | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV50104620; called by muse, mutect2, varscan2
- MRPL2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1462294193, COSV52435146; called by muse, mutect2, varscan2
- NBEAL2 | c.3868C>T p.R1290W | Missense Mutation (SNP) | VAF 3/58 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1330626921, COSV52756771; called by muse, mutect2
- NOTCH1 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53045415, COSV99484747; called by muse, mutect2
- PREB | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 136/352 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs761307766, COSV53205330; called by muse, mutect2, varscan2
- TEX9 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1195461081, COSV61877833; called by muse, mutect2, varscan2
- TTC21A | c.1991T>C p.I664T | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs781197361, COSV57184609; called by muse, mutect2, varscan2
- MED12 | c.-34_9del | Translation Start Site (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel
- ARHGAP4 | c.2160C>T p.D720= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as rs1441203366, COSV61686116; called by muse, mutect2
- DLG3 | c.978C>T p.Y326= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs370555109, COSV52079971; called by muse, mutect2, varscan2
- DNAAF4 | c.789A>G p.L263= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as rs754204516, COSV58248310; called by muse, mutect2, varscan2
- ESPL1 | c.3831A>G p.L1277= | Silent (SNP) | VAF 137/275 reads (50%) | catalogued as COSV57758914; called by muse, mutect2, varscan2
- FBXL7 | c.1392C>T p.C464= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV61644815; called by muse, mutect2, varscan2
- GPC3 | c.825C>T p.G275= | Silent (SNP) | VAF 178/349 reads (51%) | catalogued as rs753811089, COSV63662852; called by muse, mutect2, varscan2
- HEATR6 | c.2106C>T p.Y702= | Silent (SNP) | VAF 10/181 reads (6%) | catalogued as COSV51745040; called by muse, mutect2
- VPS52 | c.1026C>T p.N342= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as COSV71403462; called by muse, mutect2, varscan2
- ZMYND11 | c.663A>G p.Q221= | Silent (SNP) | VAF 93/249 reads (37%) | catalogued as rs768078919, COSV59077778; called by muse, mutect2, varscan2
- MRPL43 | c.529-2169A>T | Intron (SNP) | VAF 47/254 reads (19%) | catalogued as COSV99272479; called by muse, mutect2, varscan2
- PXN | c.831+2111C>T | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as rs746449786, COSV57218309; called by muse, mutect2, varscan2
